Somatic mutation profile of tumor specimen MBCProject_0124_T2_WES (aliquot MBCProject_0124_T2_WES_1) from CMI case MBCProject_0124, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 40.4 years (14,763 days).
Specimen MBCProject_0124_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ee021df-f7a4-4db6-9483-7392c28afc9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0124_SALIVA (Saliva), aliquot MBCProject_0124_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff975980-c8a0-421e-beec-c80f4e7627af

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD2 | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1323359345, COSV58053354; called by muse, mutect2
- CHD1 | c.4961C>T p.S1654F | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.496); catalogued as rs1217001629; called by muse, mutect2, varscan2
- SAMD9 | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV101180179; called by muse, mutect2, varscan2
- ADGRV1 | c.10526C>G p.S3509C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); called by muse, mutect2
- DSPP | c.3881G>A p.S1294N | Missense Mutation (SNP) | VAF 3/8 reads (38%) | PolyPhen possibly damaging (0.877); called by muse, mutect2
- MGAT5 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.79); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZBTB1 | c.1825C>G p.Q609E | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- C2CD3 | c.5733C>T p.L1911= | Silent (SNP) | VAF 10/12 reads (83%) | called by muse, mutect2, varscan2
- AC243965.1 | n.386C>T | RNA (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
